CCDI case PBCLNF — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/da9735ca-b7e3-40d5-8b09-6a0308b217ad

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Pineoblastoma: ICD-O-3 morphology code: 9362/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 0.3 years (105 days).

Biospecimens (3 samples)
- Sample 0DVCDP: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DVCF4: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DVCFO: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
